Somatic mutation profile of tumor specimen ALCH-ADRX-TTP1-A (aliquot ALCH-ADRX-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADRX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 73.9 years (26,976 days).
Specimen ALCH-ADRX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdeb7bf5-3fb2-4024-98a4-385e1bf0d3a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADRX-NB1-A (Blood Derived Normal), aliquot ALCH-ADRX-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d865070-b95d-444b-9464-7fceba734400

The open-access MAF lists 86 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Nonsense Mutation 8, Intron 3, RNA 2, Splice Site 1, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 76/451 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APOB | c.7859C>A p.P2620H | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263321; called by muse, mutect2
- ARHGAP29 | c.3718C>G p.Q1240E | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV53110624; called by muse, mutect2
- CARD18 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as rs1442000311; called by muse, mutect2
- CHAT | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV100340505; called by muse, mutect2
- CYP20A1 | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61910094; called by muse, mutect2
- F13A1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 27/593 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458820365, CM980653; called by muse, mutect2
- HMCN1 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772369459, COSV54942827; called by muse, mutect2
- HUWE1 | c.8945G>T p.R2982L | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs782720863, COSV104394295; called by muse, mutect2
- JAG2 | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59308213; called by muse, mutect2
- KRTAP26-1 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62128933; called by muse, mutect2
- KRTAP7-1 | c.180C>A p.N60K | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as COSV71879690; called by muse, mutect2
- NBAS | c.4486C>T p.Q1496* | Nonsense Mutation (SNP) | VAF 19/490 reads (4%) | catalogued as COSV55717057; called by muse, mutect2
- OR52N2 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 8/151 reads (5%) | catalogued as rs1446547497; called by muse, mutect2
- OR5D13 | c.427T>G p.C143G | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100687185; called by muse, mutect2
- PPARGC1B | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV58527114; called by muse, mutect2, varscan2
- RBM10 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 51/622 reads (8%) | catalogued as COSV61313311; called by muse, mutect2
- RYR2 | c.12670G>C p.E4224Q | Missense Mutation (SNP) | VAF 27/464 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV100768818, COSV63679907; called by muse, mutect2
- TBC1D22A | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs151001225; called by muse, mutect2, varscan2
- UTRN | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs78971596; called by muse, mutect2
- ZFHX4 | c.8233G>C p.E2745Q | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); catalogued as COSV51467521; called by muse, mutect2
- ZNF513 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV52009955; called by muse, mutect2
- ZNF626 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781965495; called by muse, mutect2
- AGT | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 36/567 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- ALPK1 | c.699+1G>T p.X233_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | called by muse, varscan2
- B3GNT8 | c.875T>A p.V292E | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BCAS3 | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- BTAF1 | c.2423A>G p.D808G | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CABYR | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CACNA2D1 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2
- CATSPER1 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2
- CCDC50 | c.969T>A p.H323Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- CD36 | c.1293A>T p.R431S | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- CTSG | c.126T>A p.S42R | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2
- EFCAB5 | c.3772A>T p.R1258* | Nonsense Mutation (SNP) | VAF 32/497 reads (6%) | called by muse, mutect2
- EHF | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- FMO5 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- H2BW2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.012); called by muse, mutect2
- IL1RAPL1 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2
- IQGAP2 | c.2753T>C p.V918A | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); called by muse, mutect2
- KALRN | c.7534C>G p.L2512V (on ENST00000360013 / NM_001024660.4; = p.L815V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.069); called by muse, mutect2
- KBTBD12 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCNF1 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MFN2 | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- MGAT4B | c.98-8A>T | Splice Region (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- PHF6 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 23/512 reads (4%) | called by muse, mutect2
- PKHD1 | c.731G>T p.W244L | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2
- PLOD3 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- PTPRQ | c.1156G>T p.G386* (on ENST00000616559; = p.G344* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- PTPRQ | c.1157G>C p.G386A (on ENST00000616559; = p.G344A on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2
- RYR2 | c.12320A>G p.E4107G | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SELENOV | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SH3GL2 | c.584A>C p.E195A | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- SVEP1 | c.8812G>A p.D2938N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.167); called by muse, mutect2
- SVEP1 | c.7478G>C p.C2493S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TACC2 | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); called by muse, mutect2
- USP47 | c.2948A>C p.N983T (on ENST00000399455 / NM_001372095.1; = p.N895T on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZGRF1 | c.6037C>G p.Q2013E | Missense Mutation (SNP) | VAF 29/312 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2
- ZNF613 | c.1696A>T p.K566* (on ENST00000293471 / NM_001031721.4; = p.K530* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2
- ZNF728 | c.623A>T p.K208I | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ABCA12 | c.5283C>A p.A1761= (on ENST00000272895 / NM_173076.3; = p.A1443= on NM_015657.3) | Silent (SNP) | VAF 34/599 reads (6%) | called by muse, mutect2
- ADAM30 | c.1846C>A p.R616= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs374077889; called by muse, mutect2
- C1orf141 | c.318T>C p.N106= | Silent (SNP) | VAF 11/213 reads (5%) | called by muse, mutect2
- CFAP47 | c.552C>A p.P184= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV52887022; called by muse, mutect2
- ELF4 | c.150G>C p.S50= | Silent (SNP) | VAF 38/498 reads (8%) | called by muse, mutect2
- FCF1 | c.337T>C p.L113= | Silent (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- GPR15 | c.594G>C p.V198= | Silent (SNP) | VAF 16/339 reads (5%) | called by muse, mutect2
- GRIN2B | c.711C>A p.A237= | Silent (SNP) | VAF 83/542 reads (15%) | called by muse, mutect2, varscan2
- IQCD | c.606C>T p.P202= | Silent (SNP) | VAF 21/356 reads (6%) | called by muse, mutect2
- KIF2B | c.318C>A p.I106= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3642C>T p.F1214= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs1183546243; called by muse, mutect2
- NUP210L | c.2688G>A p.L896= | Silent (SNP) | VAF 10/288 reads (3%) | called by muse, mutect2
- OR5D16 | c.732C>A p.A244= | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- RYR3 | c.4851C>T p.S1617= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs755859728, COSV66779717; called by muse, mutect2
- STRA8 | c.585C>T p.S195= (on ENST00000275764; = p.S173= on NM_182489.2) | Silent (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- TBCD | c.2923C>T p.L975= | Silent (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- UGT1A3 | c.837C>A p.I279= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as COSV59382839; called by muse, mutect2
- WFDC3 | c.117A>G p.P39= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- ZNF586 | c.45G>A p.V15= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- AGA | c.*804C>T | 3'UTR (SNP) | VAF 42/598 reads (7%) | called by muse, mutect2
- CCDC39 | n.651C>A | RNA (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- CTSLP8 | n.348G>T | RNA (SNP) | VAF 23/238 reads (10%) | called by muse, mutect2
- ERN2 | c.306+925C>A | Intron (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- GABRB3 | c.-29C>A | 5'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- GNB5 | c.864-487C>T | Intron (SNP) | VAF 25/243 reads (10%) | catalogued as rs150249128; called by muse, mutect2, varscan2
- HTN3 | c.51+26G>A | Intron (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
